Gene-level copy-number profile of tumor specimen TCGA-ZK-AAYZ-01A from TCGA case TCGA-ZK-AAYZ, project TCGA-CHOL (Cholangiocarcinoma).
Specimen TCGA-ZK-AAYZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 437aec2f-dff9-40ab-a7e7-b4290b46c5d5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-ZK-AAYZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/8aeb92c2-d902-4d58-a24e-50bd935e1d47

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 124; copy number 1: 15,703; copy number 2: 38,626; copy number 3: 2,820; copy number 4: 1,117; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 124 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,134–89,850, 7 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1.
- chr9:65,282,101–65,285,209, 1 gene: FOXD4L5.
- chr14:53,685,139–53,991,995, 6 genes (within-gene range 0–1): LINC02331, AL138479.1, MIR5580, BMP4, AL138479.2, ATP5F1CP1.
- chr15:20,228,620–20,756,183, 17 genes: RHPN2P1, CHEK2P2, AC026495.1, HERC2P3, AC023310.1, GOLGA6L6, AC023310.3, GOLGA8CP, RN7SL759P, SPATA31E2P, AC023310.2, IGHV1OR15-6, AC023310.4, NBEAP1, AC131280.1, AC012414.4, RNU6-498P.
- chr15:21,010,494–22,282,872, 72 genes (broad region; genes not listed).
- chr15:34,379,068–34,588,503, 11 genes (within-gene range 0–1): GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1.
- chr15:101,903,154–101,979,093, 10 genes: AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,238,286–7,247,571, 2 genes, copy number 5: AF228730.3, OR7E125P.

Autosomal genes at a single copy (total copy number 1): 15,659. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
